Gene-level copy-number profile of tumor specimen TCGA-IQ-A6SH-01A from TCGA case TCGA-IQ-A6SH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 55.1 years (20,109 days).
Specimen TCGA-IQ-A6SH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d2664912-702d-4d31-8ab4-ffc6a29cecdc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IQ-A6SH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fdec30d1-c9c0-457a-89e4-84b910e1471e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 4,087; copy number 2: 26,307; copy number 3: 21,010; copy number 4: 4,098; copy number 5: 2,779; copy number 6: 356; copy number 7: 244; copy number 8: 111; copy number 9: 547; copy number 10: 170; copy number 11: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IQ-A6SH-01A-12D-A34I-01): tumor purity 0.53, ploidy 2.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,890,969–190,092,279, 65 genes (broad region; genes not listed).
- chr8:22,713,251–23,230,926, 18 genes (within-gene range 0–1): PEBP4, AC037441.1, AC037441.2, RN7SL303P, AC107959.1, RHOBTB2, TNFRSF10B, AC107959.2, AC107959.3, AC107959.4, AC107959.5, TNFRSF10C, TNFRSF10D, TNFRSF10A-AS1, TNFRSF10A, RPL23AP55, AC100861.1, AC100861.2.
- chr9:9,442,060–9,803,784, 2 genes: RN7SL5P, AL513422.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,230 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:115,835,129–122,887,691, 80 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:172,137,345–204,379,792, 531 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:151,085,697–198,222,513, 826 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:58,198–5,140,119, 109 genes, copy number 9 (broad region; genes not listed).
- chr5:5,142,138–5,176,214, 1 gene, copy number 9: AC022424.1.
- chr5:6,019,029–45,895,970, 592 genes, copy number 9–11 (broad region; genes not listed).
- chr7:816,615–40,860,763, 704 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:33,580,210–41,896,762, 149 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:113,376,669–134,979,279, 285 genes, copy number 5–6 (broad region; genes not listed).
- chr12:66,767–24,562,544, 634 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:66,347,431–67,069,162, 1 gene, copy number 7 (within-gene range 4–7): GRIP1.
- chr12:66,950,754–72,186,618, 107 genes, copy number 5–7 (broad region; genes not listed).
- chr18:20,946,906–34,224,952, 210 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr21:23,704,260–23,709,345, 1 gene, copy number 5: AP000961.1.

Autosomal genes at a single copy (total copy number 1): 3,165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
